Gene-level copy-number profile of tumor specimen MP2PRT-PATTSM-TMP1-A from MP2PRT case MP2PRT-PATTSM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (846 days).
Specimen MP2PRT-PATTSM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a8a402ec-9fed-4fe1-9dcf-27fe4e7a3707.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATTSM-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/840bd312-d9ba-41a5-a01e-c4c2c647905d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 444; copy number 1: 1,704; copy number 2: 56,120; copy number 3: 118.

Homozygous deletions (total copy number 0; autosomes only): 444 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,254,015, 43 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:89,968,867–89,990,221, 3 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:90,179,889–90,221,384, 4 genes: IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr6:108,848,416–108,974,476, 4 genes: ARMC2, AL445189.1, ATP5MFP2, ARMC2-AS1.
- chr6:108,998,482–108,999,125, 1 gene (within-gene range 0–2): AL390208.1.
- chr6:111,430,260–111,606,906, 6 genes (within-gene range 0–2): BRD7P4, TRAF3IP2-AS1, AL136310.1, AL008730.1, TRAF3IP2, Z97989.1.
- chr7:38,239,580–38,340,998, 16 genes (within-gene range 0–5): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes (within-gene range 0–2): TRGV5P, TRGV5, TRGV4.
- chr9:37,002,697–37,008,040, 1 gene (within-gene range 0–2): AL161781.2.
- chr14:22,483,004–22,545,098, 52 genes (within-gene range 0–3): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31, TRAJ30, TRAJ29, TRAJ28, TRAJ27, TRAJ26, TRAJ25, TRAJ24, TRAJ23, TRAJ22, TRAJ21, TRAJ20, TRAJ19, TRAJ18, TRAJ17, TRAJ16, TRAJ14, TRAJ13, TRAJ12, TRAJ11, TRAJ10, TRAJ9, TRAJ8, TRAJ7, TRAJ6, TRAJ5, TRAJ4, TRAJ3, TRAJ2, TRAJ1.
- chr14:22,556,311–22,982,551, 27 genes: LINC02332, AC243965.1, DAD1, AC243965.2, ABHD4, OR6J1, AL160314.1, AL160314.2, OR6E1P, AL160314.3, AL135998.1, OXA1L, SLC7A7, MRPL52, MMP14, Y_RNA, Y_RNA, LRP10, REM2, RBM23, PRMT5-AS1, PRMT5, AL132780.1, HAUS4, AL132780.3, MIR4707, AJUBA.
- chr14:105,672,308–106,704,286, 158 genes (within-gene range 0–2) (broad region; genes not listed).
- chr22:22,030,934–22,171,556, 21 genes (within-gene range 0–2): IGLV4-69, IGLVI-68, AC245452.4, AC245452.3, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2, SOCS2P2.
- chr22:22,198,560–22,923,034, 105 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,704. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
